Somatic mutation profile of tumor specimen MMRF_2703_1_BM_CD138pos (aliquot MMRF_2703_1_BM_CD138pos_T1_KHS5U_L14432) from MMRF case MMRF_2703, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.4 years (21,686 days).
Specimen MMRF_2703_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7abc2e77-016a-4ac2-aec3-88540438cf3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2703_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2703_1_PB_WBC_C2_KHS5U_L14433; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6ecf5e3-cd17-41ea-b8eb-f8c28b854ddb

The open-access MAF lists 92 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 20, Intron 15, Silent 11, 3'Flank 5, RNA 4, 5'Flank 3, Nonsense Mutation 2, Splice Region 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRDT | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781291733, COSV62863797; called by muse, mutect2, varscan2
- DAB2IP | c.2263C>T p.R755C (on ENST00000408936; = p.R727C on NM_032552.3) | Missense Mutation (SNP) | VAF 163/244 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs761339512, COSV99406289; called by muse, mutect2, varscan2
- FAM47C | c.2873T>C p.I958T | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1227203170; called by muse, mutect2
- FAT1 | c.5972A>T p.N1991I | Missense Mutation (SNP) | VAF 339/512 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71675484; called by muse, mutect2, varscan2
- FLRT2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201981148, COSV58140190; called by muse, mutect2, varscan2
- HAS1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs781516429, COSV55787386; called by muse, mutect2, varscan2
- IGHV2-70 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs553609563; called by muse, varscan2
- IGHV2-70 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs367964005; called by muse, varscan2
- IGLV3-19 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs1246723964; called by muse, mutect2, varscan2
- ITGAX | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51644538; called by muse, mutect2, varscan2
- JPH3 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs746303536; called by muse, mutect2, varscan2
- MYOM1 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 137/414 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs1447424191; called by muse, mutect2, varscan2
- MYRIP | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 204/303 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530820987; called by muse, mutect2, varscan2
- PRKCQ | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 112/248 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1035888608, COSV54111827; called by muse, mutect2, varscan2
- RAB37 | c.635C>T p.S212F (on ENST00000392613 / NM_001006638.3; = p.S205F on NM_175738.5) | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1180452795; called by muse, mutect2, varscan2
- SLC26A11 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs751304381, COSV100755430; called by muse, mutect2, varscan2
- SLC7A2 | c.727A>G p.I243V (on ENST00000494857 / NM_001370338.1; = p.I283V on NM_003046.6) | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs745519823; called by muse, mutect2, varscan2
- SYPL2 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.18); catalogued as rs763021447, COSV63994886; called by muse, mutect2, varscan2
- THSD7A | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 76/112 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs754709910, COSV70271240, COSV70272675; called by muse, mutect2, varscan2
- BHLHA9 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- C3orf20 | c.747C>T p.G249= | Splice Region (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- CES1 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- LRFN1 | c.2112T>G p.Y704* | Nonsense Mutation (SNP) | VAF 114/457 reads (25%) | called by muse, mutect2, varscan2
- MAN1B1 | c.1072T>G p.F358V | Missense Mutation (SNP) | VAF 82/114 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PRUNE1 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SEC24D | c.802-1G>T p.X268_splice | Splice Site (SNP) | VAF 144/219 reads (66%) | called by muse, mutect2, varscan2
- SYCE1 | c.241T>G p.C81G (on ENST00000343131 / NM_001143764.3; = p.C45G on NM_130784.3) | Missense Mutation (SNP) | VAF 85/149 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM144 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- VWA8 | c.3281C>T p.S1094F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YTHDF2 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- ZNF738 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZSCAN2 | c.1819A>G p.T607A | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DTX1 | c.42T>G p.G14= | Silent (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- FAT4 | c.4290T>C p.V1430= | Silent (SNP) | VAF 249/379 reads (66%) | catalogued as COSV101271916; called by muse, mutect2, varscan2
- GFI1 | c.471C>T p.P157= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs756576357; called by muse, mutect2, varscan2
- IGKV4-1 | c.69G>A p.V23= | Silent (SNP) | VAF 21/21 reads (100%) | catalogued as rs545780356; called by muse, mutect2, varscan2
- NBEAL1 | c.666C>T p.A222= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs958070839; called by muse, mutect2, varscan2
- PCDHAC1 | c.1239C>T p.V413= | Silent (SNP) | VAF 79/235 reads (34%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.1362C>T p.S454= (on ENST00000611850; = p.S455= on NM_005396.5) | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as rs374767577; called by muse, mutect2, varscan2
- SYNE2 | c.1908C>G p.V636= | Silent (SNP) | VAF 84/181 reads (46%) | called by muse, mutect2, varscan2
- TGOLN2 | c.171T>C p.H57= | Silent (SNP) | VAF 112/235 reads (48%) | catalogued as rs754006343, COSV99965017; called by muse, mutect2, varscan2
- XPO7 | c.1176G>A p.P392= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs762793670, COSV99380936; called by muse, mutect2, varscan2
- ZBTB40 | c.3492G>A p.T1164= | Silent (SNP) | VAF 79/146 reads (54%) | catalogued as rs774035856, COSV100988877; called by muse, mutect2, varscan2
- AC012236.1 | n.455-51A>G | Intron (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- ACSM5P1 | n.1162G>A | RNA (SNP) | VAF 70/134 reads (52%) | catalogued as rs1159257729; called by muse, mutect2, varscan2
- ANAPC2 | c.2020+77G>A | Intron (SNP) | VAF 111/171 reads (65%) | called by muse, mutect2, varscan2
- ANKLE2 | c.182-2177C>A | Intron (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.3973+65G>A | Intron (SNP) | VAF 24/74 reads (32%) | catalogued as rs543405494; called by muse, mutect2, varscan2
- ATP8A2 | c.*2475G>A | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- BCCIP | c.850+836G>A | Intron (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- C8orf34 | c.607+280A>C | Intron (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2
- CALHM4 | chr6:116558581 T>C | 3'Flank (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- CCNC | c.346+114A>C | Intron (SNP) | VAF 100/236 reads (42%) | called by muse, mutect2, varscan2
- CHEK2 | c.1137+17A>G | Intron (SNP) | VAF 61/152 reads (40%) | called by muse, mutect2, varscan2
- CNTN5 | c.2730+918A>G | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- CYHR1 | c.247-3149G>T | Intron (SNP) | VAF 127/256 reads (50%) | called by muse, mutect2, varscan2
- DCHS2 | n.3528G>A | RNA (SNP) | VAF 108/285 reads (38%) | called by muse, mutect2, varscan2
- ELOVL2 | c.*485G>T | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- EP400P1 | n.1434_1437del | RNA (DEL) | VAF 95/227 reads (42%) | called by mutect2, pindel, varscan2
- FAM9A | c.*6T>G | 3'UTR (SNP) | VAF 158/163 reads (97%) | called by muse, mutect2, varscan2
- FETUB | c.*346G>C | 3'UTR (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.383-2566G>C | Intron (SNP) | VAF 27/46 reads (59%) | catalogued as COSV58555576; called by muse, mutect2, varscan2
- GALNT13 | c.*1435A>C | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- IFNA2 | c.*121A>C | 3'UTR (SNP) | VAF 62/208 reads (30%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4530+21052G>A | Intron (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- KREMEN1 | chr22:29143142 C>T | 3'Flank (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- LHX5 | chr12:113471904 A>C | 5'Flank (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- LINC01565 | n.1841G>T | RNA (SNP) | VAF 202/312 reads (65%) | catalogued as rs578072730; called by muse, mutect2, varscan2
- LTBP3 | c.2894-77C>T | Intron (SNP) | VAF 49/84 reads (58%) | called by muse, mutect2, varscan2
- MAP3K2 | chr2:127303341 G>A | 3'Flank (SNP) | VAF 5/36 reads (14%) | catalogued as rs1166656228; called by muse, varscan2
- MECR | c.*512G>A | 3'UTR (SNP) | VAF 65/158 reads (41%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851314 G>A | 5'Flank (SNP) | VAF 90/199 reads (45%) | catalogued as rs573318832; called by muse, mutect2, varscan2
- NLGN1 | c.*3861G>C | 3'UTR (SNP) | VAF 38/67 reads (57%) | catalogued as COSV64346102; called by muse, mutect2, varscan2
- PAPPA | c.*2519T>G | 3'UTR (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- PF4V1 | c.*11C>T | 3'UTR (SNP) | VAF 119/411 reads (29%) | catalogued as rs368211122; called by muse, mutect2, varscan2
- PPARGC1A | c.*767C>T | 3'UTR (SNP) | VAF 7/32 reads (22%) | catalogued as rs1358080748, COSV53527510; called by muse, varscan2
- PPP1R12A | c.*764G>C | 3'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- RDH10 | c.-649G>A | 5'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- RFX4 | c.*296C>A | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- RPL8 | c.-12+62C>T | Intron (SNP) | VAF 47/89 reads (53%) | called by muse, mutect2, varscan2
- RPL9 | c.259-21T>C | Intron (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- SERTM1 | c.*43C>T | 3'UTR (SNP) | VAF 13/311 reads (4%) | catalogued as rs1209169769; called by muse, mutect2
- SLC39A10 | c.*78T>G | 3'UTR (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- SNRPN | chr15:24982097 ins T | 3'Flank (INS) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- ST6GAL2 | c.*1716T>G | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- TMEM106B | c.*348A>C | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2
- TMEM237 | c.*126C>T | 3'UTR (SNP) | VAF 45/84 reads (54%) | catalogued as rs1437005789; called by muse, mutect2, varscan2
- TSPAN14 | chr10:80520209 G>A | 3'Flank (SNP) | VAF 84/149 reads (56%) | called by muse, mutect2
- TSPOAP1 | chr17:58331471 G>A | 5'Flank (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- XPR1 | c.*2338C>T | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- ZNF775 | c.*35G>C | 3'UTR (SNP) | VAF 16/157 reads (10%) | catalogued as rs951894013; called by muse, mutect2, varscan2
